Gene-level copy-number profile of tumor specimen TCGA-06-0221-01A from TCGA case TCGA-06-0221, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.0 years (11,333 days).
Specimen TCGA-06-0221-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.2d9aba03-27b7-423c-bdba-b49a443ad2d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0221-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a280ebdb-9ab3-40da-8a92-ccbf226adcd9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,672; copy number 2: 51,845; copy number 3: 2,843; copy number 4: 99; copy number 5: 26; copy number 6: 4; copy number 7: 128; copy number 8: 88; copy number 9: 31; copy number 10: 72; copy number 11: 7; copy number 12: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0221-01A-01D-0236-01): tumor purity 0.83, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 359 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–424,059, 11 genes, copy number 5: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1.
- chr4:52,440,494–55,395,847, 59 genes, copy number 7: AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1.
- chr4:55,412,636–55,412,738, 1 gene, copy number 7: Y_RNA.
- chr4:90,838,903–90,839,037, 1 gene, copy number 11: TMSB4XP8.
- chr4:130,808,507–130,967,575, 3 genes, copy number 12: AC093831.2, AC093831.1, AC093902.1.
- chr7:10,901,978–10,940,735, 3 genes, copy number 8: Y_RNA, NDUFA4, AC007029.1.
- chr7:11,006,399–11,006,876, 1 gene, copy number 9: RPL23AP52.
- chr7:26,551,686–26,647,305, 3 genes, copy number 9: AC004947.1, AC004947.3, LINC02860.
- chr7:39,621,253–39,793,092, 6 genes, copy number 10: AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3.
- chr7:68,640,798–68,641,584, 1 gene, copy number 9: AC004910.1.
- chr7:80,662,331–80,974,724, 3 genes, copy number 10: AC073850.1, SEMA3C, AC004972.1.
- chr7:92,112,159–92,917,187, 23 genes, copy number 10 (within-gene range 2–10): AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1.
- chr12:3,871,579–5,521,536, 40 genes, copy number 7: PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3, LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1, NTF3.
- chr12:5,583,797–5,584,085, 1 gene, copy number 7: AC137627.1.
- chr12:9,951,316–10,191,801, 12 genes, copy number 8 (within-gene range 2–8): CLEC12A, CLEC1B, CLEC12B, AC024224.2, CLEC9A, AC024224.1, CLEC1A, RN7SKP161, HNRNPABP1, CLEC7A, OLR1, TMEM52B.
- chr12:12,915,829–13,040,679, 9 genes, copy number 8: MIR614, GPRC5D-AS1, GPRC5D, AC007688.3, AC007688.1, HEBP1, HTR7P1, AC023790.2, AC023790.1.
- chr12:21,264,600–21,760,032, 11 genes, copy number 8 (within-gene range 2–8): SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1.
- chr12:31,244,440–31,591,136, 15 genes, copy number 7 (within-gene range 2–7): AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA.
- chr12:38,201,566–38,589,812, 7 genes, copy number 5: TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2.
- chr12:49,976,923–50,748,657, 20 genes, copy number 8 (within-gene range 2–8): RACGAP1, ASIC1, SMARCD1, GPD1, COX14, AC074032.1, CERS5, LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4, FAM186A, AC090058.1, LARP4, DIP2B, RNU6-769P, RNU6-238P.
- chr12:51,281,038–52,108,261, 26 genes, copy number 8: BIN2, CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1.
- chr12:54,353,661–54,497,688, 1 gene, copy number 8 (within-gene range 2–8): AC079313.2.
- chr12:54,428,303–54,579,239, 5 genes, copy number 8 (within-gene range 2–8): LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B.
- chr12:55,193,882–55,263,431, 4 genes, copy number 5: OR10U1P, OR10A7, OR6C74, OR6C69P.
- chr12:57,475,445–57,959,148, 40 genes, copy number 10 (within-gene range 2–10): MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.
- chr12:58,394,596–59,130,875, 8 genes, copy number 7: AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1.
- chr12:68,332,888–68,451,663, 1 gene, copy number 7 (within-gene range 2–7): LINC02384.
- chr12:68,426,331–68,487,863, 3 genes, copy number 7: AC008033.3, AC008033.1, AC008033.2.
- chr12:71,587,642–71,927,248, 12 genes, copy number 9: AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:76,259,836–76,559,809, 4 genes, copy number 6 (within-gene range 2–6): LNCOG, RN7SKP172, BBS10, OSBPL8.
- chr12:95,943,331–96,043,520, 5 genes, copy number 9 (within-gene range 2–9): AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1.
- chr12:113,789,542–114,241,770, 9 genes, copy number 9: DYNLL1P4, RBM19, AC009731.1, AC073863.1, AC010183.1, AC010183.2, HAUS8P1, GLULP5, LINC02459.
- chr12:122,726,076–122,771,064, 4 genes, copy number 5: HCAR1, AC026333.2, DENR, Y_RNA.
- chr12:127,563,908–127,732,171, 6 genes, copy number 11: AC068787.5, AC025252.1, Y_RNA, AC025252.2, LINC02411, AC025160.1.
- chr12:131,165,011–131,232,940, 1 gene, copy number 8 (within-gene range 2–8): LINC01257.

Autosomal genes at a single copy (total copy number 1): 2,286. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
